Somatic mutation profile of tumor specimen TARGET-10-PANZYY-09A (aliquot TARGET-10-PANZYY-09A-01D) from TARGET case TARGET-10-PANZYY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (552 days).
Specimen TARGET-10-PANZYY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1e19221-8a92-4823-a177-d40f275f8980.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZYY-10A (Blood Derived Normal), aliquot TARGET-10-PANZYY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f7f89e8-1bea-4faa-9d97-b3ff31c6f71d

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Splice Region 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- WFIKKN2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991730280, COSV60959244; called by muse, mutect2
- CR1 | c.6003C>T p.G2001= | Splice Region (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- TMEM200A | c.135G>A p.R45= | Silent (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- SYNPO2 | c.*5248T>A | 3'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs1009224077, COSV100205438; called by muse, mutect2, varscan2
